Somatic mutation profile of tumor specimen MP2PRT-PARMBX-TMP1-A (aliquot MP2PRT-PARMBX-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARMBX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,355 days).
Specimen MP2PRT-PARMBX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0cec46e-90cb-4846-b772-8881293d8248.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARMBX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARMBX-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c47f3e34-c139-4c4c-a36e-eb4f330d704a

The open-access MAF lists 25 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Intron 3, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL11B | c.1589C>T p.P530L (on ENST00000357195 / NM_001282237.2; = p.P459L on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 236/697 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.636); catalogued as rs1239364281; called by muse, varscan2
- CCDC114 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 86/232 reads (37%) | catalogued as rs752269093, COSV104409053; called by muse, mutect2, varscan2
- CD163 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 110/336 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs757801947, COSV63130962; called by muse, mutect2, varscan2
- CD300LB | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 99/296 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs564074862; called by muse, varscan2
- ESPNL | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 277/695 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as rs766904998; called by muse, mutect2, varscan2
- FGD5 | c.2816G>A p.R939Q | Missense Mutation (SNP) | VAF 166/493 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.029); catalogued as rs756963147, COSV53249246; called by muse, mutect2, varscan2
- GRIP2 | c.3323C>T p.A1108V (on ENST00000619221; = p.A1011V on NM_001080423.4) | Missense Mutation (SNP) | VAF 197/562 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767047626; called by muse, mutect2, varscan2
- KRT75 | c.1166C>A p.S389Y | Missense Mutation (SNP) | VAF 100/240 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV52873652; called by muse, mutect2, varscan2
- MYO1E | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 97/275 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs577478726; called by muse, mutect2, varscan2
- PPFIA2 | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV61021300, COSV61052123; called by muse, mutect2, varscan2
- RBMY1F | c.85G>T p.G29W | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58133503; called by muse, mutect2, varscan2
- SHROOM2 | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 322/418 reads (77%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as rs369881284, COSV66605016; called by muse, mutect2, varscan2
- STUB1 | c.65A>G p.K22R | Missense Mutation (SNP) | VAF 300/728 reads (41%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.087); catalogued as COSV50196848; called by muse, mutect2, varscan2
- KL | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 59/436 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- MAGEA12 | c.412A>C p.S138R | Missense Mutation (SNP) | VAF 130/180 reads (72%) | SIFT tolerated (0.15); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PKMYT1 | c.965dup p.E323* | Frame Shift Ins (INS) | VAF 103/386 reads (27%) | called by mutect2, pindel, varscan2
- SH3PXD2A | c.1252C>A p.Q418K (on ENST00000369774 / NM_001365079.1; = p.Q390K on NM_014631.2) | Missense Mutation (SNP) | VAF 19/374 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.053); called by muse, mutect2
- CDC42BPA | c.3093C>G p.S1031= (on ENST00000334218 / NM_001366019.2; = p.S1018= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/207 reads (28%) | called by muse, mutect2, varscan2
- KRTAP12-1 | c.81C>T p.P27= | Silent (SNP) | VAF 29/703 reads (4%) | catalogued as rs782613822; called by muse, mutect2
- NAIF1 | c.549C>A p.G183= | Silent (SNP) | VAF 108/379 reads (28%) | called by muse, mutect2, varscan2
- OBSCN | c.23274C>T p.A7758= | Silent (SNP) | VAF 154/397 reads (39%) | catalogued as rs1350531788; called by muse, mutect2, varscan2
- PLCB4 | c.2589C>T p.A863= | Silent (SNP) | VAF 78/229 reads (34%) | catalogued as rs373295055; called by muse, varscan2
- CSF2RA | c.1125+114G>A | Intron (SNP) | VAF 16/364 reads (4%) | catalogued as rs187465902, COSV100817620; called by muse, mutect2
- GRIN1 | c.571-805G>A | Intron (SNP) | VAF 119/323 reads (37%) | called by muse, mutect2, varscan2
- LIMCH1 | c.936-9230G>A | Intron (SNP) | VAF 78/200 reads (39%) | catalogued as rs532991644, COSV100574730; called by muse, mutect2, varscan2
